Surgical pathology report (de-identified scan), TCGA case TCGA-E8-A418, project TCGA-THCA (Thyroid Carcinoma), tissue source site Asterand, specimen TCGA-E8-A418-01A (Primary Tumor).

Procurement Date: Laterality:
Path Report: Tumor size (in cm): 9.0x9.0x6.0
Histologic type: Papillary thyroid carcinoma
Tumor extent: penetrate to fat tissue
Tumor laterality: Right
Tumor focality: Unifocal

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

7-20-12
RO

IT:PAA Discrepancy		X

1/9/12

Source: NCI Genomic Data Commons file 80c3b030-fac0-40ed-bb2f-9dd4ca45ed5b (TCGA-E8-A418.C05826F0-A01B-45AB-BB4E-38996D815CD2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).